Somatic mutation profile of tumor specimen BA2418D (aliquot aq-BA2418D) from BEATAML1.0 case 2405, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.7 years (17,440 days).
Specimen BA2418D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd10143a-56d3-410f-9a50-a4bc0c509fe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2853D (Solid Tissue Normal), aliquot aq-BA2853D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca1a3f89-6b23-414f-b8ba-dda806e58eef

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR1A | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs750233235, COSV64024212; called by mutect2, varscan2
- AFF3 | c.1633G>T p.V545L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV57845075; called by muse, mutect2
- HYDIN | c.11476G>A p.D3826N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs559637459; called by muse, mutect2, varscan2
- PIK3C2B | c.4828C>T p.R1610C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs747003072, COSV65812037; called by muse, mutect2, varscan2
- RGSL1 | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.36); catalogued as COSV54262729; called by muse, mutect2, varscan2
- CCDC120 | c.954C>A p.C318* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- PHLDB2 | c.2443T>C p.S815P (on ENST00000393925 / NM_001134439.2; = p.S772P on NM_145753.2) | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- RABEP2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2
- TEX13A | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- UBOX5 | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- WT1 | c.431_432insGG p.F144Lfs*20 | Frame Shift Ins (INS) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- MCTP1 | c.414G>T p.A138= | Silent (SNP) | VAF 20/46 reads (43%) | called by muse, varscan2
- RYR1 | c.2139C>T p.Y713= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as rs761428539, COSV62106817; ClinVar: likely benign; called by muse, mutect2, varscan2
